Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A022, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A022-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

This is a poorly differentiated carcinoma (in this case, conforming to the neuro-endocrine type, G 3), with infiltration of the terminal ileum and the serosa (p T 4) and with extensive infiltration of the lymph and blood vessels (L 1, V 1), furthermore, with free resection margins in the region of the mucosal membrane and a free ligature area and free lymph nodes (p N 0).

Tumor classification:

ICDO-DA-M 8140/3

G 3

p T 4, L 1, V 1, p N 0, M X.

ICD-0-3

Path carcinoma, NOS 8010/3

CQCF Adenocarcinoma, NOS 8140/3

Site: Cecum C18.0

lu 4/11

Source: NCI Genomic Data Commons file 25df221a-da78-47aa-a34b-fe13adc62508 (TCGA-AA-A022.E01892F7-39B5-4EC3-B8B7-733B5301AC50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).